Somatic mutation profile of tumor specimen ALCH-AE1Q-TTP1-A (aliquot ALCH-AE1Q-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-AE1Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.3 years (23,478 days).
Specimen ALCH-AE1Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cbe5db8-6351-44df-b9bb-01570d1b46cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE1Q-NB1-A (Blood Derived Normal), aliquot ALCH-AE1Q-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f485c947-e501-40e3-97f9-5342fb5a7783

The open-access MAF lists 586 somatic variants for this specimen: 418 protein-altering or splice-affecting, 115 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 361, Silent 115, Nonsense Mutation 24, Intron 22, Splice Site 12, RNA 12, Frame Shift Del 9, 3'UTR 7, 5'Flank 5, Frame Shift Ins 4, 3'Flank 4, Translation Start Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 221/443 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- AARS2 | c.2062G>T p.V688L | Missense Mutation (SNP) | VAF 186/824 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs771365295; called by muse, mutect2, varscan2
- ABCF3 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 338/588 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs981982530, COSV104393838, COSV53051637; called by muse, mutect2, varscan2
- ACSM2B | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as rs764305406; called by muse, mutect2, varscan2
- ADAMTS16 | c.2795C>G p.S932C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as COSV99940403; called by muse, mutect2, varscan2
- AR | c.2191G>T p.V731L | Missense Mutation (SNP) | VAF 214/1066 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV65955393; called by muse, mutect2, varscan2
- BORA | c.1447C>T p.Q483* (on ENST00000613797; = p.Q408* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 69/295 reads (23%) | catalogued as rs747120676; called by muse, mutect2, varscan2
- BRINP3 | c.1642C>A p.H548N | Missense Mutation (SNP) | VAF 132/619 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV66539691; called by muse, mutect2, varscan2
- C9orf24 | c.658T>A p.C220S | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV52624872; called by muse, mutect2, varscan2
- CACNA1E | c.1691C>A p.T564K | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62386712; called by muse, mutect2, varscan2
- CAMK4 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as rs1403754549; called by muse, mutect2
- CARD6 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs766607266; called by muse, mutect2, varscan2
- CCDC154 | c.1968G>T p.K656N | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs1298642356; called by muse, mutect2
- CDK12 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 144/790 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen probably damaging (0.952); catalogued as COSV70999674; called by muse, mutect2, varscan2
- CEP295 | c.5728G>T p.G1910C | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1298608142; called by muse, mutect2, varscan2
- CEP57L1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425978; called by muse, mutect2, varscan2
- CFH | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs756966643, COSV100661455, COSV62777639, COSV62778528; called by muse, mutect2, varscan2
- CHD9 | c.1754G>T p.C585F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs771444518; called by muse, mutect2, varscan2
- CLDN9 | c.583G>T p.G195* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV60910550; called by muse, mutect2
- CNTNAP2 | c.372G>C p.W124C | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62265333; called by muse, mutect2, varscan2
- CPLANE1 | c.19G>T p.V7L (on ENST00000425232; = p.V79L on NM_023073.3) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.027); catalogued as COSV57052080; called by muse, mutect2, varscan2
- CPSF1 | c.2042G>T p.R681L | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV58236108; called by muse, varscan2
- CTNNA2 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs199898826; called by muse, mutect2, varscan2
- CTNNA2 | c.2416C>T p.L806F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs774077104, COSV58133231; called by muse, mutect2, varscan2
- CWC22 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV55427545; called by muse, mutect2, varscan2
- CYP1A1 | c.1174A>G p.R392G | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1275923224; called by muse, mutect2, varscan2
- DAGLA | c.2725C>A p.Q909K | Missense Mutation (SNP) | VAF 3152/3833 reads (82%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.05); catalogued as COSV57193621; called by muse, varscan2
- DCHS1 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778093381, COSV55033999, COSV55034357; called by muse, mutect2, varscan2
- DEFB104A | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759852722; called by mutect2, varscan2
- DNAH9 | c.6964C>T p.L2322F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV99304414; called by muse, mutect2
- DSCAM | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs867374034; called by muse, mutect2, varscan2
- DUOX2 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 268/1392 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs745476904; called by muse, varscan2
- DUSP2 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV56620510; called by muse, mutect2
- ENGASE | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs200719249; called by muse, mutect2, varscan2
- EPHA7 | c.744G>T p.M248I | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV65170176; called by muse, mutect2, varscan2
- EPHB4 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 101/513 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs1330592259; called by muse, mutect2, varscan2
- EYS | c.1800G>T p.L600F | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs794727056, COSV65459361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.7343C>T p.S2448F | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55817036; called by muse, varscan2
- FAT3 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53150892; called by muse, mutect2, varscan2
- FAT3 | c.12727A>T p.S4243C | Missense Mutation (SNP) | VAF 24/758 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV53071126; called by muse, mutect2
- FLG | c.8387G>A p.G2796E | Missense Mutation (SNP) | VAF 333/2756 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV64241999; called by muse, mutect2, varscan2
- FLT1 | c.2470C>T p.R824W | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751180218, COSV99167637; called by mutect2, varscan2
- FMN2 | c.3215C>A p.A1072E | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV60426585; called by muse, varscan2
- FMR1 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782594449, COSV54427370; called by muse, mutect2, varscan2
- FREM2 | c.8227G>T p.V2743L | Missense Mutation (SNP) | VAF 190/918 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV54835663; called by muse, varscan2
- GABRG1 | c.477C>A p.H159Q | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV54954280; called by muse, mutect2, varscan2
- GATA3 | c.1197C>G p.H399Q | Missense Mutation (SNP) | VAF 54/1196 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as CD098943; called by muse, mutect2
- GMDS | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66441400; called by muse, mutect2, varscan2
- GML | c.316A>G p.N106D | Missense Mutation (SNP) | VAF 96/414 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs372983219; called by muse, mutect2, varscan2
- GPR32 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); catalogued as rs773267384; called by muse, mutect2, varscan2
- GRIN2A | c.2745G>C p.M915I | Missense Mutation (SNP) | VAF 111/569 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100411396; called by muse, mutect2, varscan2
- GRIP2 | c.908C>T p.P303L (on ENST00000619221; = p.P206L on NM_001080423.4) | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs1004522653; called by muse, mutect2
- HS2ST1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 117/664 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as rs1381205399; called by muse, mutect2, varscan2
- IGHV1-69 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 140/318 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs782402688; called by mutect2, varscan2
- IGHV3-21 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 234/1393 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as rs180974163; called by muse, mutect2, varscan2
- IGSF9B | c.2787C>A p.S929R | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58071286; called by muse, mutect2, varscan2
- IL9R | c.308C>G p.T103S | Missense Mutation (SNP) | VAF 364/773 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs770230398; called by muse, mutect2, varscan2
- ITGA10 | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100994997; called by muse, mutect2, varscan2
- JAKMIP1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs557009257, COSV51539456; called by muse, mutect2, varscan2
- KALRN | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 141/625 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53752030; called by muse, mutect2, varscan2
- KEAP1 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 222/443 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407360; called by mutect2, varscan2
- KIF1A | c.3728+1G>A p.X1243_splice (on ENST00000320389 / NM_001379639.1; = p.X1344_splice on NM_001379638.1) | Splice Site (SNP) | VAF 69/513 reads (13%) | catalogued as rs1345972494; called by muse, mutect2, varscan2
- LAMA4 | c.3074A>G p.Y1025C (on ENST00000230538 / NM_001105206.3; = p.Y1018C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/521 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs370557242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC70 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as rs750312307; called by muse, mutect2, varscan2
- MCTP1 | c.2309C>G p.S770C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100386707; called by muse, mutect2, varscan2
- MGRN1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 19/580 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1389726955; called by muse, mutect2
- MMP16 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV54163619; called by muse, mutect2
- MORC1 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1239837592; called by muse, mutect2, varscan2
- MUC4 | c.7540C>G p.P2514A | Missense Mutation (SNP) | VAF 164/2100 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.55); catalogued as rs758933644; called by muse, mutect2
- MYH4 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 168/692 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs970629889; called by muse, mutect2, varscan2
- NAT10 | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1181851214; called by muse, mutect2, varscan2
- NBAS | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 73/362 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as COSV55721943; called by muse, mutect2, varscan2
- NCAPG2 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 46/418 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs765636505; called by muse, mutect2, varscan2
- NCBP3 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1486375863; called by muse, mutect2, varscan2
- NCOA3 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs754780052; called by muse, mutect2, varscan2
- NES | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63962920; called by muse, mutect2
- NFX1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 60/792 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1436594571, COSV59311384; called by muse, mutect2
- NKAIN3 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60656931; called by muse, mutect2
- NR1H4 | c.925G>T p.V309L (on ENST00000551379 / NM_001206993.2; = p.V295L on NM_005123.4) | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV99501164; called by muse, mutect2, varscan2
- NUP153 | c.4030A>G p.I1344V | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs535067637; called by muse, mutect2, varscan2
- OR5D14 | c.477G>C p.L159F | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as rs1331365532, COSV59455226; called by muse, mutect2, varscan2
- OR5F1 | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs780899733, COSV53547432, COSV99558435; called by muse, mutect2, varscan2
- OR5L2 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV65723794; called by muse, mutect2, varscan2
- OR5M8 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs772332403; called by muse, mutect2, varscan2
- OR8J3 | c.724del p.A242Lfs*4 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as COSV56882607; called by mutect2, pindel, varscan2
- OTX2 | c.143C>G p.A48G (on ENST00000408990 / NM_172337.3; = p.A56G on NM_021728.4) | Missense Mutation (SNP) | VAF 173/531 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV59766165; called by muse, mutect2, varscan2
- PABPC5 | c.556C>G p.R186G | Missense Mutation (SNP) | VAF 177/625 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57040504; called by muse, mutect2, varscan2
- PAK5 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 56/381 reads (15%) | catalogued as COSV62034955; called by muse, mutect2, varscan2
- PCDH15 | c.5108C>T p.S1703L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV57276335; called by muse, mutect2, varscan2
- PCDHB4 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 37/378 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.06); catalogued as COSV52023581; called by muse, mutect2, varscan2
- PCDHGB4 | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53942996; called by muse, mutect2, varscan2
- PCNT | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs1291503523, COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- PI4KA | c.4538C>T p.P1513L | Missense Mutation (SNP) | VAF 117/399 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs767554127; called by muse, mutect2, varscan2
- PKHD1 | c.3787C>T p.P1263S | Missense Mutation (SNP) | VAF 148/590 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.131); catalogued as rs1208007711; called by muse, mutect2, varscan2
- PKHD1L1 | c.5980G>A p.V1994I | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV65745048; called by muse, mutect2, varscan2
- PNMA8A | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs765742161; called by muse, mutect2, varscan2
- POTEG | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 228/3344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770750981; called by muse, mutect2
- PRKCE | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 345/1810 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60324227; called by muse, mutect2, varscan2
- PRR5L | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 26/751 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1209690054; called by muse, mutect2
- PSD4 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.026); catalogued as rs1285290102; called by muse, mutect2, varscan2
- PSG8 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 147/842 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60610757; called by muse, mutect2, varscan2
- PTPRN2 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1203075510; called by muse, mutect2, varscan2
- RD3 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 277/1342 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs750239049, COSV65362804; called by muse, mutect2, varscan2
- REG1B | c.64+1G>T p.X22_splice | Splice Site (SNP) | VAF 34/145 reads (23%) | catalogued as COSV59306959; called by muse, mutect2, varscan2
- RIMBP2 | c.712del p.R238Gfs*36 | Frame Shift Del (DEL) | VAF 116/570 reads (20%) | catalogued as COSV55469326, COSV55475139, COSV55479677; called by mutect2, pindel, varscan2
- RIMS2 | c.2299G>T p.V767F (on ENST00000666250 / NM_001348490.2; = p.V575F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51668555; called by muse, mutect2, varscan2
- RYR2 | c.5210C>A p.T1737N | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.114); catalogued as rs1172292367; called by muse, varscan2
- SCN5A | c.4500G>T p.K1500N (on ENST00000333535 / NM_198056.3; = p.K1499N on NM_000335.5) | Missense Mutation (SNP) | VAF 198/513 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs199473265, CD004174; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SDC3 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs200515984; called by muse, mutect2, varscan2
- SEMA5A | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792007; called by muse, mutect2, varscan2
- SERPINB12 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV54032304; called by muse, mutect2, varscan2
- SH3TC1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 42/189 reads (22%) | catalogued as COSV55289436; called by muse, mutect2, varscan2
- SHISAL2A | c.411C>A p.Y137* | Nonsense Mutation (SNP) | VAF 87/385 reads (23%) | catalogued as rs1252370784; called by muse, mutect2, varscan2
- SIGLEC12 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 165/479 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.421); catalogued as COSV52463978; called by muse, mutect2, varscan2
- SKIL | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52058544; called by muse, mutect2, varscan2
- SLC26A3 | c.1149A>G p.I383M | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); catalogued as CD112527; called by muse, mutect2, varscan2
- SLC45A1 | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as COSV57101201; called by muse, mutect2, varscan2
- SLC6A5 | c.1173G>T p.E391D | Missense Mutation (SNP) | VAF 187/868 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs553897287; called by muse, mutect2, varscan2
- SORCS1 | c.1546G>T p.V516L | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs369987397, CM124365; called by muse, mutect2, varscan2
- SORCS1 | c.1037T>A p.L346Q | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs752270204; called by muse, mutect2, varscan2
- SPHKAP | c.3537C>G p.S1179R | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100764062; called by muse, mutect2, varscan2
- SYNE2 | c.7490C>T p.S2497L | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs778422950; called by muse, mutect2, varscan2
- SYTL2 | c.1795C>T p.L599F (on ENST00000528231 / NM_001162951.2; = p.L1888F on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV60360805; called by muse, mutect2
- TAS2R4 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV56093294; called by muse, varscan2
- TGDS | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1183728299; called by muse, mutect2, varscan2
- TPTE | c.1423G>A p.D475N (on ENST00000618007 / NM_199261.4; = p.D457N on NM_199259.4) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1314927846; called by muse, mutect2
- TTLL5 | c.3481C>T p.Q1161* | Nonsense Mutation (SNP) | VAF 18/282 reads (6%) | catalogued as COSV54033326; called by muse, mutect2
- TXNIP | c.498_500del p.K167del | In Frame Del (DEL) | VAF 31/177 reads (18%) | catalogued as rs782691020; called by mutect2, pindel, varscan2
- TYW1B | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs1554477901; called by muse, mutect2, varscan2
- UBL4A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782359606, COSV54837142; called by muse, mutect2
- USP26 | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as rs1343374761; called by muse, mutect2, varscan2
- ZFHX4 | c.8685C>A p.N2895K | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV50648141; called by muse, mutect2
- ZNF257 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV71309326; called by muse, mutect2, varscan2
- ZNF365 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 104/602 reads (17%) | catalogued as COSV67925299; called by muse, mutect2, varscan2
- ZNF518A | c.2972C>A p.S991Y | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV60152678; called by muse, mutect2, varscan2
- ZNF676 | c.277G>T p.D93Y (on ENST00000650058; = p.D61Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs568114767; called by muse, varscan2
- ZNF727 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.32); catalogued as COSV70702056; called by muse, mutect2, varscan2
- ZNF735 | c.585del p.C195* | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | catalogued as COSV70036072; called by mutect2, pindel, varscan2
- ABCB1 | c.3540_3546del p.Q1180Hfs*5 | Frame Shift Del (DEL) | VAF 105/386 reads (27%) | called by mutect2, pindel, varscan2
- ACKR4 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.103); called by muse, varscan2
- ACSM2B | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 87/537 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ADAMTS20 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ADGRG4 | c.2542T>G p.Y848D | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ALOX5AP | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 85/438 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ALPK2 | c.5788C>T p.H1930Y | Missense Mutation (SNP) | VAF 266/972 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ALPK3 | c.5017A>G p.S1673G | Missense Mutation (SNP) | VAF 163/771 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKK1 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 145/673 reads (22%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ANKRD34B | c.634A>T p.K212* | Nonsense Mutation (SNP) | VAF 58/302 reads (19%) | called by mutect2, varscan2
- ANKRD34B | c.285A>T p.K95N | Missense Mutation (SNP) | VAF 85/425 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ANKRD7 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 96/551 reads (17%) | called by muse, mutect2, varscan2
- ANP32D | c.394T>A p.*132Rext*107 | Nonstop Mutation (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- APBB1 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 88/469 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- APBB1IP | c.738C>A p.D246E | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- AR | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 104/456 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ASXL1 | c.1409C>A p.S470Y | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ATRX | c.2948A>T p.K983M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- BAZ1B | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- BIRC3 | c.280A>G p.R94G | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BIRC7 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALCR | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CARD14 | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- CBLC | c.445T>A p.Y149N | Missense Mutation (SNP) | VAF 152/457 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCR6 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CD1C | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 69/556 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD34 | c.143C>A p.T48K | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH19 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CENPK | c.288+1G>T p.X96_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- CEP170 | c.3814G>A p.G1272R | Missense Mutation (SNP) | VAF 32/777 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CETN2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CFAP54 | c.7258G>A p.V2420M | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CNOT2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNST | c.1480G>T p.G494* | Nonsense Mutation (SNP) | VAF 128/590 reads (22%) | called by muse, mutect2, varscan2
- CNTN5 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2
- COL11A1 | c.2087C>A p.P696Q | Missense Mutation (SNP) | VAF 101/500 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- COL11A2 | c.1007del p.G336Afs*46 | Frame Shift Del (DEL) | VAF 134/664 reads (20%) | called by mutect2, pindel, varscan2
- COL2A1 | c.2744G>A p.G915E | Missense Mutation (SNP) | VAF 155/572 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A1 | c.4512C>G p.F1504L | Missense Mutation (SNP) | VAF 137/1072 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- COL5A2 | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 40/872 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A3 | c.6016C>A p.L2006M | Missense Mutation (SNP) | VAF 144/650 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL9A1 | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- COL9A3 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CPEB1 | c.1304dup p.L435Ffs*8 (on ENST00000617958; = p.L370Ffs*8 on NM_030594.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 64/278 reads (23%) | called by mutect2, pindel, varscan2
- CPED1 | c.2633G>T p.R878M | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPLANE1 | c.8216G>C p.G2739A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CPNE8 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CRYBG3 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CRYGB | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CSMD3 | c.3418G>C p.D1140H (on ENST00000297405 / NM_001363185.1; = p.D1036H on NM_052900.3) | Missense Mutation (SNP) | VAF 75/393 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CST5 | c.329A>C p.Q110P | Missense Mutation (SNP) | VAF 82/338 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CSTF1 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- CXorf66 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP39A1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAB1 | c.1666G>T p.E556* (on ENST00000371231; = p.E523* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/214 reads (25%) | called by muse, mutect2, varscan2
- DAGLA | c.2672C>A p.S891Y | Missense Mutation (SNP) | VAF 2328/2826 reads (82%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, varscan2
- DCAF8L2 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.173); called by muse, varscan2
- DCAF8L2 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- DCC | c.1054T>C p.C352R | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDC | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 167/546 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLGAP1 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAH10 | c.6028A>T p.K2010* (on ENST00000409039; = p.K1949* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 97/486 reads (20%) | called by muse, mutect2, varscan2
- DNAH5 | c.8329A>G p.T2777A | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DNHD1 | c.8885C>G p.T2962S | Missense Mutation (SNP) | VAF 162/645 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DSC3 | c.2499G>T p.L833F | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DTHD1 | c.889G>T p.V297F (on ENST00000456874; = p.V132F on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTWD1 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DYNC1H1 | c.3178T>G p.L1060V | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F7 | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EFCAB8 | c.393C>G p.Y131* | Nonsense Mutation (SNP) | VAF 64/442 reads (14%) | called by muse, mutect2, varscan2
- EHHADH | c.10T>G p.Y4D | Missense Mutation (SNP) | VAF 88/872 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- EPHB6 | c.2094G>C p.Q698H | Missense Mutation (SNP) | VAF 134/669 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERMARD | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2
- ESYT1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.625A>C p.K209Q | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FADS1 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 19/607 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM135B | c.102G>C p.L34F | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FAM228B | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAR2 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAR2 | c.1188C>A p.N396K | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- FCRL1 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 87/518 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FMO1 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- FOXI2 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FREM3 | c.4744C>A p.H1582N | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- GBA3 | c.622T>G p.Y208D | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GEN1 | c.636G>A p.K212= | Splice Region (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- GFM1 | c.1946T>A p.I649N | Missense Mutation (SNP) | VAF 59/425 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GGPS1 | c.680G>C p.S227T | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GLP1R | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 118/553 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLRA2 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNRHR | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 106/562 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GORAB | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 97/491 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- HARS2 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 92/659 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HARS2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 92/661 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEPACAM2 | c.704C>A p.P235H (on ENST00000394468 / NM_001039372.4; = p.P223H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC1 | c.12295G>A p.E4099K | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- HERC2 | c.6950G>T p.R2317L | Missense Mutation (SNP) | VAF 153/690 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HIP1 | c.804-1G>T p.X268_splice | Splice Site (SNP) | VAF 107/440 reads (24%) | called by muse, mutect2, varscan2
- HSPA1L | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 134/617 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- IFNW1 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- IGHG3 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 267/971 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IGKV1-6 | c.128T>A p.I43N | Missense Mutation (SNP) | VAF 213/993 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- IGKV3D-11 | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 206/522 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.045); called by mutect2, varscan2
- IGKV3D-11 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 216/606 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IL36A | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 159/820 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INPP5D | c.866C>T p.S289F (on ENST00000445964 / NM_001017915.3; = p.S288F on NM_005541.5) | Missense Mutation (SNP) | VAF 132/699 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- IRX4 | c.721A>G p.S241G | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, varscan2
- ISOC2 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ITIH6 | c.2443C>G p.L815V | Missense Mutation (SNP) | VAF 155/356 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ITPKB | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 218/818 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ITPRID1 | c.1329C>A p.N443K | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KANK1 | c.1983del p.V662Sfs*31 | Frame Shift Del (DEL) | VAF 122/401 reads (30%) | called by mutect2, pindel, varscan2
- KBTBD8 | c.65del p.P22Qfs*27 | Frame Shift Del (DEL) | VAF 202/743 reads (27%) | called by mutect2, pindel, varscan2
- KCNA6 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.211); called by muse, mutect2
- KCNH6 | c.1614C>A p.F538L | Missense Mutation (SNP) | VAF 204/889 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KDM6A | c.444-3C>A | Splice Region (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2
- KLHL33 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 233/642 reads (36%) | called by muse, mutect2, varscan2
- KTN1 | c.2145G>C p.Q715H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- LAMA3 | c.7565G>T p.G2522V (on ENST00000313654 / NM_198129.4; = p.G913V on NM_000227.6) | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LCE1A | c.151T>A p.C51S | Missense Mutation (SNP) | VAF 484/1376 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.978); called by muse, varscan2
- LMO7 | c.2487A>C p.K829N (on ENST00000357063; = p.K510N on NM_005358.5) | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- LMOD2 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- LNP1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 91/408 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LRGUK | c.2202del p.K735Rfs*7 | Frame Shift Del (DEL) | VAF 42/252 reads (17%) | called by mutect2, pindel, varscan2
- MAP3K5 | c.1756A>T p.I586F | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MCM8 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- MCM9 | c.2561A>T p.E854V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- MTFR2 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 101/445 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTX2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
- MUC16 | c.28193C>G p.A9398G | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MUC16 | c.19136C>A p.S6379* | Nonsense Mutation (SNP) | VAF 78/229 reads (34%) | called by muse, mutect2, varscan2
- MYEF2 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 106/471 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- MYLK | c.4964T>A p.V1655D | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYO10 | c.2694G>T p.E898D | Missense Mutation (SNP) | VAF 108/713 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO16 | c.1879C>A p.Q627K | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYO18B | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 63/420 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MYOM1 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NAALAD2 | c.2064_2065insT p.K689* | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- NLGN1 | c.1672C>G p.Q558E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP4 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NOX4 | c.353T>A p.V118E | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NR1H4 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NR1I3 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 46/489 reads (9%) | called by muse, mutect2, varscan2
- NSA2 | c.191+1G>T p.X64_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- NSFL1C | c.648-2A>T p.X216_splice | Splice Site (SNP) | VAF 73/275 reads (27%) | called by muse, mutect2, varscan2
- NT5C1A | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OCRL | c.2678G>A p.G893D | Missense Mutation (SNP) | VAF 312/750 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OLFM4 | c.51A>T p.Q17H | Missense Mutation (SNP) | VAF 119/616 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- OR10G7 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 62/880 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- OR10G9 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- OR4F6 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR51L1 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR52W1 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 21/624 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR56B4 | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- OR8D2 | c.470C>A p.T157K | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2
- OR8G1 | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR8H2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8J1 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PARD3 | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PARG | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PARP15 | c.815dup p.N272Kfs*20 (on ENST00000464300 / NM_001113523.3; = p.N38Kfs*20 on NM_152615.2) | Frame Shift Ins (INS) | VAF 40/244 reads (16%) | called by mutect2, pindel, varscan2
- PARP6 | c.1029G>T p.R343S | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PCDHA11 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 70/315 reads (22%) | called by muse, varscan2
- PCDHA3 | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 244/1080 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PCDHB12 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHB6 | c.1540C>A p.L514I | Missense Mutation (SNP) | VAF 300/1611 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, varscan2
- PDE6B | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 104/551 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PDE6C | c.1798T>C p.F600L | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE8A | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZRN4 | c.1481G>T p.W494L (on ENST00000402685 / NM_001164595.2; = p.W236L on NM_013377.4) | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLCE1 | c.4377G>T p.K1459N | Missense Mutation (SNP) | VAF 124/648 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLD1 | c.1580A>G p.D527G | Missense Mutation (SNP) | VAF 168/343 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR1C | c.831C>G p.N277K | Missense Mutation (SNP) | VAF 168/674 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PPP1R17 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R3A | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP3R1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PPP3R2 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 172/619 reads (28%) | called by muse, mutect2, varscan2
- PROB1 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR16 | c.285C>G p.I95M (on ENST00000407149 / NM_001300783.2; = p.I72M on NM_016644.2) | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PSG8 | c.44G>C p.W15S | Missense Mutation (SNP) | VAF 150/843 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSMA2 | c.555A>C p.E185D | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTCD1 | c.1900T>C p.Y634H | Missense Mutation (SNP) | VAF 108/552 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTN | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PTPN13 | c.4870dup p.V1624Gfs*9 (on ENST00000411767 / NM_080683.3; = p.V1605Gfs*9 on NM_006264.3) | Frame Shift Ins (INS) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- PTPRK | c.1711A>T p.I571L | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPRZ1 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRZ1 | c.4574A>T p.Q1525L | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RAB2B | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- REM1 | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RFXAP | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS18 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- RHPN1 | c.598A>C p.T200P | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMBP2 | c.1763C>A p.P588H | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RIMS1 | c.2738A>T p.E913V | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RNF17 | c.233C>G p.T78R | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR3 | c.2798T>A p.L933Q | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCART1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 124/471 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCML4 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SEC16B | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 243/874 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SENP7 | c.3146G>T p.S1049I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SF3B4 | c.1088-1G>T p.X363_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- SFRP4 | c.593-2A>T p.X198_splice | Splice Site (SNP) | VAF 52/133 reads (39%) | called by muse, mutect2, varscan2
- SGCG | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGSM3 | c.1902+2T>A p.X634_splice | Splice Site (SNP) | VAF 128/531 reads (24%) | called by muse, varscan2
- SHCBP1L | c.353G>T p.W118L | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SHISA8 | c.415C>G p.R139G (on ENST00000457093; = p.R172G on NM_001207020.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC15A2 | c.1579G>A p.V527I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A1 | c.680del p.G227Efs*11 | Frame Shift Del (DEL) | VAF 143/759 reads (19%) | called by mutect2, pindel, varscan2
- SLC9A2 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SMG8 | c.2488G>T p.A830S | Missense Mutation (SNP) | VAF 85/454 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMIM23 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 100/618 reads (16%) | called by mutect2, varscan2
- SMYD1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 98/468 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SOBP | c.2064G>T p.R688S | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.037); called by muse, mutect2
- SOGA1 | c.2815G>C p.V939L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SOWAHC | c.1036C>A p.H346N | Missense Mutation (SNP) | VAF 142/595 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP9 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- SPATA31D1 | c.1922C>G p.S641C | Missense Mutation (SNP) | VAF 124/596 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEG | c.3704G>T p.R1235L | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- SPIN2B | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 123/469 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRSF5 | c.-21A>T | Splice Region (SNP) | VAF 21/466 reads (5%) | called by muse, mutect2
- SSMEM1 | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ST3GAL4 | c.873G>T p.Q291H (on ENST00000392669 / NM_001254758.1; = p.Q287H on NM_006278.3) | Missense Mutation (SNP) | VAF 67/625 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- STEAP3 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 46/771 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUCLA2 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2, varscan2
- SYN1 | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 118/531 reads (22%) | called by muse, mutect2, varscan2
- SYNE1 | c.13043T>C p.V4348A (on ENST00000367255 / NM_182961.4; = p.V4277A on NM_033071.3) | Missense Mutation (SNP) | VAF 96/591 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TANC1 | c.2529G>T p.L843F | Missense Mutation (SNP) | VAF 84/456 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- TANC1 | c.2530G>T p.A844S | Missense Mutation (SNP) | VAF 84/467 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TBL1XR1 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- TBX19 | c.1099A>T p.S367C | Missense Mutation (SNP) | VAF 398/1117 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TCEAL1 | c.318G>T p.L106F | Missense Mutation (SNP) | VAF 156/623 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM1 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX51 | c.535G>T p.G179C (on ENST00000643416; = p.D155Y on NM_001322244.2) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2
- TIAM2 | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TIMELESS | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 117/458 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TLL2 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TM7SF3 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 105/676 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TMEM132C | c.1884C>G p.D628E | Missense Mutation (SNP) | VAF 101/432 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMEM132C | c.2387G>T p.R796M | Missense Mutation (SNP) | VAF 99/547 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TMEM204 | c.676T>C p.C226R | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TMEM229B | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 31/790 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2
- TMEM59L | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- TNF | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 200/877 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TNIK | c.3208C>T p.L1070F | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOR1AIP1 | c.1412A>G p.N471S | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TRAF1 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRAV12-2 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 85/245 reads (35%) | called by muse, mutect2, varscan2
- TRIM49B | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TRIM64B | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 48/414 reads (12%) | called by muse, varscan2
- TRIM64C | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- TRPM1 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 228/1042 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TRPM6 | c.2444A>G p.H815R | Missense Mutation (SNP) | VAF 124/469 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TSPAN10 | c.646C>A p.L216M (on ENST00000574882 / NM_001290212.1; = p.L178M on NM_031945.4) | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2
- TTC34 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TTC7A | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TTN | c.53194T>C p.C17732R (on ENST00000591111; = p.C10308R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TTN | c.18901C>A p.P6301T (on ENST00000591111; = p.P5374T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/124 reads (17%) | PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.8597C>T p.A2866V (on ENST00000591111; = p.A2820V on NM_003319.4) | Missense Mutation (SNP) | VAF 110/536 reads (21%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC79 | c.1321G>T p.E441* (on ENST00000393151 / NM_001346218.2; = p.E264* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 42/184 reads (23%) | called by muse, varscan2
- VNN1 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 51/443 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWCE | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWF | c.4327G>T p.V1443L | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WNK2 | c.682-1G>C p.X228_splice | Splice Site (SNP) | VAF 56/151 reads (37%) | called by muse, varscan2
- WNT8B | c.103-2A>T p.X35_splice | Splice Site (SNP) | VAF 40/223 reads (18%) | called by muse, mutect2, varscan2
- WSCD2 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 120/423 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAR1 | c.1022G>C p.S341T | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF185 | c.759A>T p.K253N | Missense Mutation (SNP) | VAF 193/413 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ZNF19 | c.427A>T p.T143S | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF407 | c.2857C>A p.P953T | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.4434G>T p.E1478D | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF444 | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZNF451 | c.962A>T p.H321L | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF622 | c.1199A>T p.Y400F | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF782 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF835 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 162/513 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF845 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ZRANB3 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ABCA7 | c.6408C>T p.L2136= | Silent (SNP) | VAF 90/417 reads (22%) | called by muse, mutect2, varscan2
- ABCB4 | c.1146G>A p.E382= | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as COSV55933595, COSV55939916; called by muse, mutect2
- ACSM2B | c.489C>A p.V163= | Silent (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.849G>A p.G283= | Silent (SNP) | VAF 90/420 reads (21%) | catalogued as COSV60901493; called by muse, mutect2, varscan2
- ALDH7A1 | c.948A>G p.P316= | Silent (SNP) | VAF 149/807 reads (18%) | called by muse, mutect2, varscan2
- ALK | c.3270C>A p.T1090= | Silent (SNP) | VAF 278/1071 reads (26%) | catalogued as COSV66585209; called by mutect2, varscan2
- ANGPTL3 | c.90T>C p.S30= | Silent (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2475T>C p.F825= | Silent (SNP) | VAF 40/193 reads (21%) | called by muse, mutect2, varscan2
- AP002512.3 | c.942C>G p.L314= | Silent (SNP) | VAF 65/333 reads (20%) | catalogued as COSV99688053; called by muse, mutect2, varscan2
- APLNR | c.186C>G p.R62= | Silent (SNP) | VAF 75/308 reads (24%) | called by muse, mutect2, varscan2
- APOB | c.9438A>T p.P3146= | Silent (SNP) | VAF 55/226 reads (24%) | called by muse, mutect2, varscan2
- ARGLU1 | c.27G>T p.S9= | Silent (SNP) | VAF 177/539 reads (33%) | called by muse, mutect2, varscan2
- ATP13A2 | c.1464G>T p.L488= | Silent (SNP) | VAF 20/474 reads (4%) | called by muse, mutect2
- BANK1 | c.1806G>T p.G602= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- BRINP3 | c.2112A>G p.L704= | Silent (SNP) | VAF 124/351 reads (35%) | catalogued as rs778280914, COSV66541032; called by muse, mutect2, varscan2
- C1QTNF1 | c.837C>T p.T279= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs751188970; called by muse, mutect2
- C8B | c.1521C>A p.P507= | Silent (SNP) | VAF 122/570 reads (21%) | called by muse, mutect2, varscan2
- CALCR | c.1113G>A p.Q371= (on ENST00000649521 / NM_001164737.2; = p.Q355= on NM_001742.4) | Silent (SNP) | VAF 88/551 reads (16%) | called by muse, mutect2, varscan2
- CAPN6 | c.948T>A p.V316= | Silent (SNP) | VAF 56/184 reads (30%) | called by muse, varscan2
- CCDC198 | c.723C>A p.G241= | Silent (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- CCL4L2 | c.276C>G p.V92= (on ENST00000617405 / NM_001291475.2; = p.S89* on NM_001291471.2) | Silent (SNP) | VAF 302/1910 reads (16%) | called by mutect2, varscan2
- CD36 | c.982C>T p.L328= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- CDC42BPA | c.288A>G p.L96= | Silent (SNP) | VAF 53/164 reads (32%) | called by muse, mutect2, varscan2
- CNBD1 | c.954T>C p.R318= | Silent (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- COL24A1 | c.111A>G p.A37= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs191835956; called by muse, mutect2, varscan2
- DCLK3 | c.1227C>T p.L409= | Silent (SNP) | VAF 101/862 reads (12%) | called by muse, mutect2, varscan2
- DENND4B | c.3498G>T p.L1166= | Silent (SNP) | VAF 71/336 reads (21%) | called by muse, mutect2, varscan2
- DNAJC3 | c.834C>T p.L278= | Silent (SNP) | VAF 38/245 reads (16%) | catalogued as rs1298503571; called by muse, mutect2, varscan2
- DYNC1LI1 | c.51A>G p.L17= | Silent (SNP) | VAF 214/472 reads (45%) | called by muse, mutect2, varscan2
- ECE2 | c.93C>A p.P31= | Silent (SNP) | VAF 119/873 reads (14%) | catalogued as rs912674865; called by muse, mutect2, varscan2
- EFR3B | c.1219C>A p.R407= | Silent (SNP) | VAF 92/433 reads (21%) | called by muse, mutect2, varscan2
- EPB41L2 | c.504A>G p.L168= | Silent (SNP) | VAF 34/195 reads (17%) | called by muse, mutect2, varscan2
- ERICH3 | c.4371A>T p.A1457= | Silent (SNP) | VAF 86/356 reads (24%) | catalogued as COSV58610305; called by muse, mutect2, varscan2
- EXOSC7 | c.666G>T p.S222= | Silent (SNP) | VAF 146/477 reads (31%) | catalogued as rs1161677585, COSV55557336; called by muse, mutect2, varscan2
- FBXO43 | c.1708C>A p.R570= | Silent (SNP) | VAF 85/367 reads (23%) | catalogued as COSV101413852, COSV71054139, COSV71055382; called by muse, mutect2, varscan2
- FBXW11 | c.276G>T p.V92= | Silent (SNP) | VAF 27/141 reads (19%) | called by muse, mutect2, varscan2
- FJX1 | c.1176C>T p.Y392= | Silent (SNP) | VAF 274/1195 reads (23%) | called by muse, mutect2, varscan2
- GLIS3 | c.1737C>A p.V579= | Silent (SNP) | VAF 97/374 reads (26%) | called by muse, mutect2, varscan2
- GRIN1 | c.585G>T p.L195= | Silent (SNP) | VAF 196/694 reads (28%) | called by muse, varscan2
- GRK7 | c.315G>A p.A105= | Silent (SNP) | VAF 15/315 reads (5%) | catalogued as rs1366037105, COSV53824817; called by muse, mutect2
- H1-5 | c.408G>T p.G136= | Silent (SNP) | VAF 212/900 reads (24%) | catalogued as COSV100137763; called by muse, mutect2, varscan2
- HEY2 | c.187C>A p.R63= | Silent (SNP) | VAF 48/236 reads (20%) | catalogued as COSV64240521; called by muse, varscan2
- IFNL2 | c.243C>G p.P81= | Silent (SNP) | VAF 14/414 reads (3%) | catalogued as COSV100122087; called by muse, mutect2
- IFNW1 | c.240C>A p.L80= | Silent (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- IL18RAP | c.1725C>A p.T575= | Silent (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- ITGAM | c.111C>T p.S37= | Silent (SNP) | VAF 62/358 reads (17%) | catalogued as rs777607162, COSV99791719; called by muse, mutect2, varscan2
- KRT1 | c.1452C>A p.T484= | Silent (SNP) | VAF 243/1138 reads (21%) | catalogued as rs1401303658, COSV52865326; called by muse, mutect2, varscan2
- LGALS9C | c.690C>T p.T230= | Silent (SNP) | VAF 194/1170 reads (17%) | catalogued as rs1214120345; called by muse, varscan2
- LMO7 | c.1776A>G p.A592= (on ENST00000357063; = p.A322= on NM_015842.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/276 reads (24%) | called by muse, mutect2, varscan2
- LRP1B | c.2409G>T p.G803= | Silent (SNP) | VAF 77/333 reads (23%) | called by muse, varscan2
- LRRC2 | c.39C>T p.I13= | Silent (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- LRRC52 | c.543G>A p.L181= | Silent (SNP) | VAF 131/856 reads (15%) | catalogued as rs1333984882; called by muse, mutect2, varscan2
- MAGEC1 | c.3345G>A p.Q1115= | Silent (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- MAN2A1 | c.1998C>T p.V666= | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- MPPED2 | c.606C>T p.L202= | Silent (SNP) | VAF 36/267 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.26754G>A p.E8918= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV101198916; called by muse, mutect2
- NLRC3 | c.2490C>G p.L830= | Silent (SNP) | VAF 69/457 reads (15%) | called by muse, mutect2, varscan2
- NLRC5 | c.5136G>T p.L1712= | Silent (SNP) | VAF 20/618 reads (3%) | called by muse, mutect2
- NRG3 | c.243C>T p.L81= | Silent (SNP) | VAF 100/435 reads (23%) | catalogued as rs1010732697, COSV100932182; called by muse, mutect2, varscan2
- NUP188 | c.1056G>A p.L352= | Silent (SNP) | VAF 141/581 reads (24%) | catalogued as COSV101001151; called by muse, mutect2, varscan2
- OBSL1 | c.1524C>T p.L508= | Silent (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- OR10G4 | c.702C>G p.R234= | Silent (SNP) | VAF 43/279 reads (15%) | called by muse, mutect2, varscan2
- OR13C3 | c.657T>C p.C219= | Silent (SNP) | VAF 45/152 reads (30%) | called by muse, mutect2, varscan2
- OR2G3 | c.27A>G p.L9= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100180529; called by muse, mutect2, varscan2
- OR2T2 | c.324G>T p.L108= | Silent (SNP) | VAF 174/1872 reads (9%) | catalogued as COSV61619372; called by muse, mutect2
- OR4K15 | c.879A>G p.K293= (on ENST00000305051; = p.K269= on NM_001005486.1) | Silent (SNP) | VAF 61/358 reads (17%) | called by muse, mutect2, varscan2
- OR5I1 | c.606C>T p.S202= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as COSV56886864; called by muse, mutect2, varscan2
- OR6F1 | c.12C>A p.G4= | Silent (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- OR8D1 | c.690C>A p.S230= | Silent (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- ORC6 | c.240G>A p.Q80= | Silent (SNP) | VAF 14/357 reads (4%) | called by muse, mutect2
- OVCH1 | c.1527G>C p.T509= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV58965393, COSV58968345; called by muse, mutect2, varscan2
- PAPPA | c.3879C>A p.V1293= | Silent (SNP) | VAF 73/291 reads (25%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2175G>T p.A725= | Silent (SNP) | VAF 130/668 reads (19%) | catalogued as COSV63540850, COSV63544256; called by muse, mutect2, varscan2
- PCDHB5 | c.1551G>T p.S517= | Silent (SNP) | VAF 348/1608 reads (22%) | catalogued as COSV50662826; called by muse, mutect2, varscan2
- PCDHGB7 | c.1698G>T p.A566= | Silent (SNP) | VAF 65/320 reads (20%) | called by muse, mutect2, varscan2
- PDCD1 | c.744T>C p.Y248= | Silent (SNP) | VAF 97/385 reads (25%) | called by muse, mutect2, varscan2
- PDE9A | c.885C>G p.L295= | Silent (SNP) | VAF 142/509 reads (28%) | called by muse, mutect2, varscan2
- PJA1 | c.1278G>T p.G426= (on ENST00000361478 / NM_145119.4; = p.G238= on NM_022368.5) | Silent (SNP) | VAF 147/499 reads (29%) | called by muse, mutect2, varscan2
- PLAC8L1 | c.444C>G p.S148= | Silent (SNP) | VAF 54/371 reads (15%) | called by muse, mutect2, varscan2
- PLAGL1 | c.768G>A p.L256= | Silent (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- PLPPR4 | c.2154G>C p.L718= | Silent (SNP) | VAF 136/632 reads (22%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.54G>C p.L18= | Silent (SNP) | VAF 24/454 reads (5%) | catalogued as COSV100179644; called by muse, mutect2
- PRAMEF17 | c.201A>T p.G67= | Silent (SNP) | VAF 317/1055 reads (30%) | called by muse, mutect2, varscan2
- PREX1 | c.3702T>A p.A1234= | Silent (SNP) | VAF 167/753 reads (22%) | called by muse, mutect2, varscan2
- PRRC1 | c.321A>G p.V107= | Silent (SNP) | VAF 40/233 reads (17%) | catalogued as COSV99688089; called by muse, mutect2, varscan2
- PSD | c.2712G>A p.V904= | Silent (SNP) | VAF 52/160 reads (33%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.300G>A p.A100= | Silent (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- RBMXL3 | c.1425A>G p.Q475= | Silent (SNP) | VAF 71/288 reads (25%) | called by muse, mutect2, varscan2
- RFX4 | c.2019C>A p.P673= (on ENST00000392842 / NM_213594.3; = p.P579= on NM_032491.6) | Silent (SNP) | VAF 114/531 reads (21%) | called by muse, mutect2, varscan2
- RGN | c.459C>G p.S153= | Silent (SNP) | VAF 15/300 reads (5%) | catalogued as COSV60275560; called by muse, mutect2
- RGS4 | c.492C>T p.S164= | Silent (SNP) | VAF 308/955 reads (32%) | catalogued as rs11544157; called by muse, mutect2, varscan2
- RIC1 | c.2538C>G p.L846= | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- RNF139 | c.1197G>T p.L399= | Silent (SNP) | VAF 39/249 reads (16%) | called by muse, mutect2, varscan2
- RNF148 | c.525C>G p.V175= | Silent (SNP) | VAF 88/383 reads (23%) | called by muse, mutect2, varscan2
- RNF32 | c.264G>T p.P88= | Silent (SNP) | VAF 35/244 reads (14%) | catalogued as COSV58735244; called by muse, mutect2, varscan2
- RYR2 | c.5211C>A p.T1737= | Silent (SNP) | VAF 40/305 reads (13%) | called by muse, varscan2
- RYR2 | c.5931C>T p.L1977= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV63684765; called by muse, mutect2, varscan2
- SLC35E4 | c.1020G>C p.L340= | Silent (SNP) | VAF 40/146 reads (27%) | called by muse, mutect2
- SLU7 | c.525A>T p.P175= | Silent (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- TAS2R8 | c.444A>G p.A148= | Silent (SNP) | VAF 50/248 reads (20%) | called by muse, mutect2, varscan2
- TCF7 | c.1047G>A p.S349= | Silent (SNP) | VAF 96/469 reads (20%) | catalogued as rs754914783, COSV58656468; called by muse, mutect2, varscan2
- TMEM174 | c.465C>T p.S155= | Silent (SNP) | VAF 100/459 reads (22%) | called by muse, mutect2, varscan2
- TMEM199 | c.63G>A p.L21= | Silent (SNP) | VAF 214/1169 reads (18%) | called by muse, mutect2, varscan2
- TMEM229A | c.543G>T p.R181= | Silent (SNP) | VAF 106/593 reads (18%) | called by muse, mutect2, varscan2
- TMEM262 | c.102C>T p.I34= (on ENST00000530719 / NM_001282448.1; = p.I32= on NM_001242631.2) | Silent (SNP) | VAF 24/758 reads (3%) | called by muse, mutect2
- TMIGD3 | c.651C>T p.C217= (on ENST00000369717 / NM_001081976.2; = p.C298= on NM_020683.7) | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- TNXB | c.8664T>C p.P2888= (on ENST00000647633; = p.P2641= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 208/950 reads (22%) | catalogued as rs748340354; called by muse, mutect2
- TPO | c.1932C>A p.L644= | Silent (SNP) | VAF 265/1420 reads (19%) | called by muse, mutect2, varscan2
- UBE3B | c.1578G>A p.L526= | Silent (SNP) | VAF 81/369 reads (22%) | called by muse, mutect2, varscan2
- UNC13C | c.5709A>T p.S1903= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- VIP | c.261C>T p.T87= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as COSV65889276, COSV65889391; called by muse, varscan2
- VPS51 | c.2277T>A p.S759= | Silent (SNP) | VAF 267/532 reads (50%) | called by muse, mutect2, varscan2
- VWC2 | c.627G>T p.P209= | Silent (SNP) | VAF 103/291 reads (35%) | catalogued as rs1375476425; called by muse, mutect2, varscan2
- ZP4 | c.333A>T p.G111= | Silent (SNP) | VAF 301/916 reads (33%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.933G>A p.V311= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs1222615269; called by muse, mutect2, varscan2
- AC004951.3 | n.9C>A | RNA (SNP) | VAF 158/492 reads (32%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148287 G>T | 5'Flank (SNP) | VAF 200/401 reads (50%) | called by muse, mutect2, varscan2
- AC100872.1 | chr8:122670518 T>C | 5'Flank (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- AC136759.1 | n.771G>A | RNA (SNP) | VAF 62/374 reads (17%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1262G>C | RNA (SNP) | VAF 118/592 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.-72C>G | 5'UTR (SNP) | VAF 27/143 reads (19%) | catalogued as rs1038342141; called by muse, mutect2, varscan2
- ALG10B | c.171+26C>G | Intron (SNP) | VAF 92/523 reads (18%) | called by muse, mutect2, varscan2
- AMT | c.696+31A>T | Intron (SNP) | VAF 269/830 reads (32%) | called by muse, mutect2, varscan2
- AP5Z1 | c.1806-67del | Intron (DEL) | VAF 271/712 reads (38%) | called by mutect2, pindel, varscan2
- ATAD3A | chr1:1509292 A>G | 5'Flank (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- CCDC144CP | n.3283A>G | RNA (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- CD1C | c.*11C>A | 3'UTR (SNP) | VAF 43/256 reads (17%) | catalogued as COSV63806798; called by muse, mutect2, varscan2
- CEP162 | c.*52G>T | 3'UTR (SNP) | VAF 31/213 reads (15%) | called by muse, mutect2, varscan2
- CRB1 | c.1172-7085G>A | Intron (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- DMKN | c.1039-581G>T | Intron (SNP) | VAF 179/438 reads (41%) | called by muse, mutect2, varscan2
- EYA4 | c.278-10T>C | Intron (SNP) | VAF 49/426 reads (12%) | catalogued as rs761823494, COSV100766091; called by muse, mutect2, varscan2
- FRG2KP | chr16:31569269 C>T | 5'Flank (SNP) | VAF 185/1272 reads (15%) | called by muse, mutect2, varscan2
- GCSAML | c.140-81C>A | Intron (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- HDAC8 | c.1111+551G>A | Intron (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.388G>C | RNA (SNP) | VAF 37/194 reads (19%) | called by muse, mutect2, varscan2
- KRT7 | chr12:52252035 A>G | 3'Flank (SNP) | VAF 85/396 reads (21%) | catalogued as rs1282495571; called by muse, mutect2, varscan2
- LRMDA | c.*4C>A | 3'UTR (SNP) | VAF 79/320 reads (25%) | called by muse, mutect2, varscan2
- LYRM9 | c.219+138C>T | Intron (SNP) | VAF 184/439 reads (42%) | called by muse, mutect2, varscan2
- MIR1827 | n.42G>A | RNA (SNP) | VAF 70/422 reads (17%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12919T>A | Intron (SNP) | VAF 98/379 reads (26%) | called by muse, mutect2, varscan2
- NBPF22P | n.1066C>T | RNA (SNP) | VAF 176/1436 reads (12%) | called by muse, mutect2, varscan2
- NDUFA6 | c.*33A>G | 3'UTR (SNP) | VAF 17/343 reads (5%) | catalogued as rs955358791; called by muse, mutect2
- OR2L1P | n.398G>C | RNA (SNP) | VAF 78/396 reads (20%) | called by muse, mutect2, varscan2
- OR2W5 | n.1110C>A | RNA (SNP) | VAF 136/715 reads (19%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156192 G>A | 3'Flank (SNP) | VAF 81/351 reads (23%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227376 G>T | 3'Flank (SNP) | VAF 136/523 reads (26%) | called by muse, mutect2, varscan2
- RBBP7 | c.17-299A>T | Intron (SNP) | VAF 89/243 reads (37%) | called by muse, mutect2, varscan2
- RGS6 | c.1369-11916C>G | Intron (SNP) | VAF 89/540 reads (16%) | called by muse, mutect2, varscan2
- RNF17 | c.1240+887G>T | Intron (SNP) | VAF 28/145 reads (19%) | called by muse, mutect2, varscan2
- SATB2 | c.1173+95G>T | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- SERPINA3 | c.917+51C>T | Intron (SNP) | VAF 92/469 reads (20%) | called by muse, varscan2
- SHCBP1L | chr1:182953331 G>A | 5'Flank (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- SLC17A8 | c.*40C>A | 3'UTR (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088448 G>A | 3'Flank (SNP) | VAF 16/92 reads (17%) | catalogued as rs906292863; called by muse, mutect2, varscan2
- SNORD116-23 | n.17C>A | RNA (SNP) | VAF 56/292 reads (19%) | called by muse, mutect2, varscan2
- SRCIN1 | c.-1G>A | 5'UTR (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- SREBF2 | c.1204+26C>G | Intron (SNP) | VAF 182/939 reads (19%) | called by muse, mutect2, varscan2
- ST3GAL4 | c.3+114G>C | Intron (SNP) | VAF 75/387 reads (19%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.422A>G | RNA (SNP) | VAF 154/994 reads (15%) | called by muse, varscan2
- TRIP12 | c.2352+20G>T | Intron (SNP) | VAF 151/695 reads (22%) | called by muse, mutect2, varscan2
- TSPAN19 | c.265-1265A>T | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- UGT2B27P | n.615T>A | RNA (SNP) | VAF 40/185 reads (22%) | called by muse, mutect2, varscan2
- UXS1 | c.1028-227G>C | Intron (SNP) | VAF 164/703 reads (23%) | called by muse, mutect2, varscan2
- WDFY4 | c.*164C>T | 3'UTR (SNP) | VAF 20/640 reads (3%) | called by muse, mutect2
- ZEB2 | c.73+3511G>T | Intron (SNP) | VAF 168/689 reads (24%) | called by muse, varscan2
- ZNF747 | c.*392C>G | 3'UTR (SNP) | VAF 108/294 reads (37%) | called by muse, mutect2, varscan2
- ZNF853 | c.-41G>T | 5'UTR (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.3019-401A>C | Intron (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
